MMRF case MMRF_1671 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/8e5f4b05-55a4-4507-a1cf-f44b5485315e

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 68 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 68.6 years (25,073 days); ISS stage: I; Days to last known disease status: 1,129 days (3.1 years); Days to last follow up: 1,129 days (3.1 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 394 days (1.1 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 141 days; Days to treatment end: 407 days (1.1 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 449 days (1.2 years); Days to treatment end: 547 days (1.5 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 449 days (1.2 years); Days to treatment end: 547 days (1.5 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 548 days (1.5 years); Days to treatment end: 903 days (2.5 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Third line of therapy; Days to treatment start: 877 days (2.4 years); Days to treatment end: 903 days (2.5 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Third line of therapy; Days to treatment start: 877 days (2.4 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Third line of therapy; Days to treatment start: 904 days (2.5 years); Days to treatment end: 1,050 days (2.9 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 904 days (2.5 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Third line of therapy; Days to treatment start: 1,051 days (2.9 years); Days to treatment end: 1,071 days (2.9 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Third line of therapy; Days to treatment start: 1,072 days (2.9 years); Days to treatment end: 1,128 days (3.1 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 1,128 days (3.1 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -31 (ECOG 1): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 200 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.544 mg/dL; Immunoglobulin G 10.4 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 2.7 µg/mL; Hemoglobin 8.25 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 259 ×10⁹/L; Creatinine 99.9 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.45 mmol/L; Albumin 44 g/L; Total Protein 6.9 g/dL; Glucose 5.01 mmol/L.
- Day 70 (ECOG 0): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 258 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.77 mg/dL; Immunoglobulin G 7.5 g/L; Immunoglobulin A 0.11 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 6.57 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 230 ×10⁹/L; Creatinine 102 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 6.2 g/dL; Glucose 8.75 mmol/L.
- Day 156 (ECOG 1): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 82.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.477 mg/dL; Immunoglobulin G 6.22 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.15 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 6 g/dL; Glucose 5.94 mmol/L.
- Day 239 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.05 mg/dL; Immunoglobulin G 5.01 g/L; Immunoglobulin A 0.31 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 1.93 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 5.7 g/dL; Glucose 6.99 mmol/L.
- Day 323 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 24.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.919 mg/dL; Immunoglobulin G 5.79 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 2.1 µg/mL; Lactate Dehydrogenase 1.97 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 209 ×10⁹/L; Creatinine 95.5 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 5.8 g/dL; Glucose 5.83 mmol/L.
- Day 407 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 22.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.09 mg/dL; Immunoglobulin G 6.02 g/L; Immunoglobulin A 0.37 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.03 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 188 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 6.2 g/dL; Glucose 6 mmol/L.
- Day 505 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 24.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.809 mg/dL; Immunoglobulin G 5.88 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.26 g/L; Hemoglobin 7.94 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 95.5 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 6.1 g/dL; Glucose 7.15 mmol/L.
- Day 590 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 32.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.23 mg/dL; Immunoglobulin G 7.21 g/L; Immunoglobulin A 0.53 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 7.56 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 127 ×10⁹/L; Creatinine 95.5 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.15 mmol/L; Albumin 39 g/L; Total Protein 6.1 g/dL; Glucose 4.84 mmol/L.
- Day 701 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 31.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.73 mg/dL; Immunoglobulin G 11.1 g/L; Immunoglobulin A 0.88 g/L; Immunoglobulin M 0.34 g/L; Beta 2 Microglobulin 2.65 µg/mL; Lactate Dehydrogenase 1.83 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 143 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.35 mmol/L; Albumin 39 g/L; Total Protein 6.5 g/dL; Glucose 5.01 mmol/L.
- Day 792 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 79.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.49 mg/dL; Immunoglobulin G 11.2 g/L; Immunoglobulin A 0.8 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 2.55 µg/mL; Lactate Dehydrogenase 1.55 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 214 ×10⁹/L; Creatinine 95.5 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 6.5 g/dL; Glucose 5.39 mmol/L.
- Day 865 (ECOG 0): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 128 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.42 mg/dL; Immunoglobulin G 11.5 g/L; Immunoglobulin A 0.59 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 3.2 µg/mL; Lactate Dehydrogenase 1.62 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 121 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 6.9 g/dL; Glucose 5.39 mmol/L.
- Day 960 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.6 mg/dL; Immunoglobulin G 5.37 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 3.58 µg/mL; Lactate Dehydrogenase 2.17 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 186 ×10⁹/L; Creatinine 107 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.2 mmol/L; Albumin 39 g/L; Total Protein 5.9 g/dL; Glucose 6.44 mmol/L.
- Day 1,044 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 97.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.57 mg/dL; Immunoglobulin G 5.52 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 3.47 µg/mL; Lactate Dehydrogenase 2.25 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 114 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.38 mmol/L; Albumin 39 g/L; Total Protein 6 g/dL; Glucose 6.38 mmol/L.
- Day 1,129 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 114 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.44 mg/dL; Beta 2 Microglobulin 2.31 µg/mL; Hemoglobin 8.06 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 118 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.38 mmol/L; Albumin 39 g/L; Total Protein 6 g/dL; Glucose 7.87 mmol/L.

Other clinical attributes
- Day -31: Weight: 75 kg; Height: 167 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Lung Cancer.

Biospecimens (4 samples)
- Sample MMRF_1671_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -31 days.
- Sample MMRF_1671_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 323 days.
- Sample MMRF_1671_4_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 865 days (2.4 years).
- Sample MMRF_1671_4_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 865 days (2.4 years).
